Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3846, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3846-01A (Primary Tumor).

Diagnosis:

This is a poorly differentiated adenocarcinoma of the sigmoid colon of histopathological differentiation grade G3, with erosions of the inner tumor surface, with peritumorous chronic recurrent secondary inflammation with an acute inflammatory flare, with tumor infiltration of the colon wall layers as far as the pericolic fatty connective tissue, with carcinomatous lymphangitis, with tumor-free lymph nodes (0/16) with moderate chronic lymphadenitis and tumor-free overview slices from all other parts of the resection material described.

According to the section preparations available, the tumor spread of the sigmoid carcinoma corresponds to the tumor stage pT3, pN0 (0/16), MX, L1, R0

with regard to the so-called radial resection margin, this shows a mature, predominantly fatty connective tissue,

with regard to the lymph nodes, these show a metastasis (1 of 13) of the carcinoma described.

Summary tumor classification:

ICDO-DA M-8140/3

G3

Source: NCI Genomic Data Commons file a57e77fc-43b1-47cf-b4a5-c07da0b7d2ee (TCGA-AA-3846.5096C73E-2A6B-4302-B397-E6B2161C081C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).